Gene-level copy-number profile of tumor specimen TCGA-09-2048-01A from TCGA case TCGA-09-2048, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.1 years (23,043 days).
Specimen TCGA-09-2048-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e9e4ff48-9076-426f-a229-9d3b139dc811.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-09-2048-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/33d4df24-7586-4878-b99d-901f8f189f64

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 9; copy number 2: 11,222; copy number 3: 40; copy number 4: 31,598; copy number 5: 3,517; copy number 6: 8,688; copy number 7: 221; copy number 8: 2,403; copy number 9: 144; copy number 10: 539; copy number 13: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-09-2048-01): tumor purity 0.99, ploidy 2.1, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:241,881,363–242,088,457, 8 genes (within-gene range 0–6): LINC01237, FAM240C, LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 691 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,044,883–209,328,535, 315 genes, copy number 10 (broad region; genes not listed).
- chr2:185,652,374–185,800,151, 1 gene, copy number 9 (within-gene range 6–9): FSIP2-AS1.
- chr2:185,738,804–186,422,432, 4 genes, copy number 9 (within-gene range 6–9): FSIP2, RPL21P32, LINC01473, AC104058.1.
- chr3:164,978,898–174,378,005, 135 genes, copy number 9 (broad region; genes not listed).
- chr3:197,445,061–198,123,232, 30 genes, copy number 10: AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1.
- chr6:29,887,294–29,934,286, 8 genes, copy number 13: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.
- chr11:74,171,267–83,423,516, 194 genes, copy number 10 (broad region; genes not listed).
- chr12:63,558,913–63,795,718, 4 genes, copy number 9 (within-gene range 8–9): DPY19L2, AC084357.2, AC027667.1, AC084357.3.

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
